Somatic mutation profile of tumor specimen 0D8H9T from CCDI case PBBHHZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 7.6 years (2,780 days).
Specimen 0D8H9T: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60facc12-5df0-46ee-b0d7-e8a7c91d2b86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D8H9V (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1de0915a-b832-45e9-831a-b08bc1cd987f

The open-access MAF lists 23 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Frame Shift Del 2, Intron 2, 3'UTR 2, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHI1 | c.1934G>A p.R645H | Missense Mutation (SNP) | VAF 338/761 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs772513002; called by muse, mutect2, varscan2
- FBXW7 | c.1832del p.G611Dfs*17 (on ENST00000281708 / NM_001349798.2; = p.G531Dfs*17 on NM_018315.5) | Frame Shift Del (DEL) | VAF 74/504 reads (15%) | catalogued as COSV55909812; called by mutect2, varscan2
- RAD21 | c.1013G>C p.R338T | Missense Mutation (SNP) | VAF 90/467 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV52056811; called by muse, mutect2, varscan2
- SDK2 | c.4534C>T p.P1512S | Missense Mutation (SNP) | VAF 64/1008 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1172698655; called by muse, mutect2
- SYT16 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 30/1036 reads (3%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1460582050; called by muse, mutect2
- UNC80 | c.6317C>G p.S2106C | Missense Mutation (SNP) | VAF 31/936 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs915022648; called by muse, mutect2
- ANKRD26 | c.4225C>T p.L1409F | Missense Mutation (SNP) | VAF 55/368 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- ARID4A | c.3525T>A p.N1175K | Missense Mutation (SNP) | VAF 23/616 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2
- EFCAB6 | c.2917T>G p.F973V | Missense Mutation (SNP) | VAF 32/780 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2
- KCNJ3 | c.1245del p.K415Nfs*3 | Frame Shift Del (DEL) | VAF 120/779 reads (15%) | called by mutect2, varscan2
- KMT2C | c.1217G>C p.C406S | Missense Mutation (SNP) | VAF 167/649 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ROBO2 | c.2105T>C p.L702P | Missense Mutation (SNP) | VAF 109/709 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTBL2 | c.75C>T p.D25= | Silent (SNP) | VAF 364/859 reads (42%) | catalogued as rs374948712; called by muse, mutect2, varscan2
- AMY2A | c.1215A>G p.Q405= | Silent (SNP) | VAF 92/2639 reads (3%) | called by muse, mutect2
- CRMP1 | c.840C>T p.A280= | Silent (SNP) | VAF 68/730 reads (9%) | catalogued as rs374628256; called by muse, mutect2
- DIAPH3 | c.42C>T p.G14= | Silent (SNP) | VAF 265/556 reads (48%) | called by muse, mutect2, varscan2
- MEIS1 | c.57C>T p.I19= | Silent (SNP) | VAF 75/667 reads (11%) | called by muse, mutect2, varscan2
- AC073648.1 | n.497C>A | RNA (SNP) | VAF 70/806 reads (9%) | called by muse, mutect2
- ACSS1 | c.*69C>T | 3'UTR (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- C17orf64 | c.*63A>G | 3'UTR (SNP) | VAF 20/627 reads (3%) | called by muse, mutect2
- SLC12A1 | c.724+421G>A | Intron (SNP) | VAF 5/24 reads (21%) | catalogued as rs1164576074; called by muse, mutect2
- SLC35A2 | chrX:48911675 A>G | 5'Flank (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- TATDN1 | c.138+54T>A | Intron (SNP) | VAF 10/180 reads (6%) | called by muse, mutect2
